Gene-level copy-number profile of tumor specimen TCGA-FG-7637-01A from TCGA case TCGA-FG-7637, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 49.5 years (18,084 days).
Specimen TCGA-FG-7637-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.ab8d414d-1563-4d06-97a3-0b509d8d711f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FG-7637-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate.
https://portal.gdc.cancer.gov/files/3ba05fbd-7d67-412e-8786-365cc69b0816

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,932; copy number 2: 50,461; copy number 3: 2,427.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 4,551. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
